Gene-level copy-number profile of tumor specimen TCGA-CV-5973-01A from TCGA case TCGA-CV-5973, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.3 years (22,771 days).
Specimen TCGA-CV-5973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.14757096-1a1c-47c7-91aa-bba678a20cd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5973-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c42ac1a-beb7-4a62-a1b7-a4e0e6215ce8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 578; copy number 2: 15,792; copy number 3: 30,433; copy number 4: 10,967; copy number 5: 160; copy number 6: 762; copy number 7: 153; copy number 8: 104; copy number 9: 609; copy number 14: 38; copy number 17: 41; copy number 18: 1; copy number 19: 62; copy number 20: 25; copy number 25: 61; copy number 32: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5973-01A-11D-1682-01): tumor purity 0.7, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,115 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,274,338–98,313,299, 61 genes, copy number 25 (within-gene range 2–25) (broad region; genes not listed).
- chr5:58,198–3,601,403, 92 genes, copy number 7 (broad region; genes not listed).
- chr10:58,512,872–64,693,446, 62 genes, copy number 14–20 (within-gene range 1–20) (broad region; genes not listed).
- chr11:62,832,342–66,509,657, 241 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:69,294,151–69,367,726, 1 gene, copy number 9 (within-gene range 6–9): MYEOV.
- chr11:69,371,463–94,740,355, 594 genes, copy number 8–32 (broad region; genes not listed).
- chr11:95,482,406–95,497,553, 1 gene, copy number 18 (within-gene range 2–18): AP001790.1.
- chr11:98,130,239–98,131,198, 1 gene, copy number 20: AP001317.1.
- chr11:100,336,856–103,895,271, 62 genes, copy number 19 (within-gene range 2–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 578. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
